Gene-level copy-number profile of tumor specimen C3L-08230-04 from CPTAC case C3L-08230, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 86.5 years (31,597 days).
Specimen C3L-08230-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b30b480-38dc-4436-a2d3-36f0892ae0f9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08230-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/65fbe201-636a-4779-a311-4227ca19217f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 816; copy number 2: 26,340; copy number 3: 23,530; copy number 4: 6,008; copy number 5: 1,401; copy number 6: 147; copy number 7: 21; copy number 9: 8; copy number 11: 1; copy number 12: 1; copy number 16: 4; copy number 64: 7; copy number 65: 4; copy number 107: 18; copy number 124: 3; copy number 126: 2; copy number 127: 4; copy number 131: 6; copy number 134: 2; copy number 137: 1; copy number 142: 2; copy number 187: 10; copy number 214: 2; copy number 229: 11; copy number 236: 4; copy number 250: 4; copy number 286: 3; copy number 402: 2.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr4:9,459,255–9,484,702, 2 genes: OR7E86P, OR7E85P.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:9,090,898–9,091,245, 1 gene (within-gene range 0–2): RPS26P3.
- chr11:112,967–186,136, 5 genes (within-gene range 0–3): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–2): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–5): RPS10P2.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–5): RNU6-1159P, RNU6-115P.
- chr22:18,533,646–18,577,968, 1 gene: PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,668 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:99,952,033–99,952,158, 1 gene, copy number 6: AC004522.1.
- chr10:42,149,310–42,281,819, 5 genes, copy number 5: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr11:55,602,360–55,666,195, 4 genes, copy number 6: OR4C11, OR4P4, OR4S2, OR4C6.
- chr13:47,745,736–48,037,968, 1 gene, copy number 5 (within-gene range 3–5): SUCLA2.
- chr13:47,825,330–50,906,856, 69 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:72,453,902–76,135,225, 52 genes, copy number 5: AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561, LINC01034, RN7SL571P.
- chr17:16,804,627–16,845,881, 5 genes, copy number 5: AC022596.1, NOS2P4, KRT16P6, KRT16P2, KRT17P1.
- chr17:28,950,513–29,057,216, 5 genes, copy number 9–16 (within-gene range 2–16): PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4.
- chr17:31,830,731–31,901,708, 4 genes, copy number 127: AC004253.2, COPRS, UTP6, AC004253.1.
- chr17:32,083,179–32,491,253, 28 genes, copy number 107–187: AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,509,954–32,531,492, 5 genes, copy number 64 (within-gene range 2–202): AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.
- chr17:32,876,759–32,997,877, 4 genes, copy number 64–214 (within-gene range 2–214): AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:39,566,915–39,864,312, 15 genes, copy number 7–286: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr17:40,121,971–40,565,472, 24 genes, copy number 7–9: MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7.
- chr17:41,665,566–41,836,260, 10 genes, copy number 65–131 (within-gene range 2–131): AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B.
- chr17:45,784,280–45,895,680, 3 genes, copy number 124 (within-gene range 2–124): CRHR1, MAPT-AS1, SPPL2C.
- chr17:50,525,520–50,627,474, 6 genes, copy number 126–236 (within-gene range 2–236): AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3.
- chr17:53,105,734–53,106,358, 1 gene, copy number 5: MTCO1P40.
- chr17:53,681,630–53,682,111, 1 gene, copy number 7: AC034268.1.
- chr17:64,542,282–64,847,728, 13 genes, copy number 229–402 (within-gene range 2–402): SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9.
- chr17:67,774,591–68,047,364, 9 genes, copy number 6–12: RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2.
- chr20:87,250–16,053,197, 286 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 5 (within-gene range 0–5): MACROD2-AS1.
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 5–6 (broad region; genes not listed).
- chr21:10,482,738–13,016,692, 7 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Autosomal genes at a single copy (total copy number 1): 810. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
